Surgical pathology report (de-identified scan), TCGA case TCGA-IF-A4AK, project TCGA-SARC (Sarcoma), tissue source site University of Texas MD Anderson Cancer Center, specimen TCGA-IF-A4AK-01A (Primary Tumor).

Specimen Date/Time:

DIAGNOSIS:

(A) RADICAL EXCISION RIGHT THIGH TUMOR:
LEIOMYOSARCOMA.

No tumor seen at margins.

(B) NEW DEEP MARGIN RIGHT THIGH:

No tumor seen.

ICD-0-3

leiomyosarcoma, NOS 8890/3

Site: thigh, NOS C49.2

fw
9/24/12

GROSS DESCRIPTION:

(A) RADICAL EXCISION RIGHT THIGH SARCOMA, SHORT PROXIMAL, LONG ANTERIOR – Received is an irregular portion of fibroadipose tissue measuring 10.5 cm proximal to distal, 6.5 cm anterior to posterior and 2.2 cm superior to inferior. Specimen is surfaced by an ellipse of tan, grossly unremarkable skin measuring 10.0 x 4.2 cm. Specimen is oriented by the surgeon as follows: short stitch proximal, long stitch anterior. Specimen is inked as follows: Black - deep, blue - anterior, yellow - posterior. Specimen is serially sectioned from proximal to distal into twelve slices. Cut surfaces reveal a 3.2 x 2.4 x 2.2 cm well-circumscribed gray-white firm lobulated mass that is located in slices #5-7. This lobulated mass comes to within 0.7 cm of the deep margin, 1.2 cm of the anterior margin and 1.3 cm of the posterior margin. The proximal and distal margins are widely free of tumor. The remaining cut surfaces are yellow glistening lobulated adipose tissue. Representative tumor and normal tissue are submitted to the sarcoma bank. Representative sections are submitted.

INK CODE: Black - deep, black - anterior, yellow - posterior.

SECTION CODE: A1-A9, representative sections submitted from sequential order from proximal to distal as follows: A1, proximal margin; A2, tissue adjacent to tumor; A3, tumor including deep margin; A4, tumor including posterior margin; A5, tumor including anterior margin; A6, tumor including skin; A7, tumor; A8, tissue adjacent to tumor; A9, distal margin.

DX: CIRCUMSCRIBED TUMOR ALMOST ABUTS DEEP MARGIN. BUT CAN BE STRETCHED TO 3-MM. FASCIA MOVES FREELY UNDER TUMOR. OTHER MARGINS 1 CM OR GREATER.

(B) NEW DEEP MARGIN, RIGHT THIGH – A 5.5 x 2.5 x 0.5 cm tissue, has short and long stitches indicating proximal and anterior margins, respectively. The true margin is marked with clips. The specimen is inked, cross sectioned and submitted in toto in B1-B8.

INK CODE: Black – true margin, orange – proximal margin, black - anterior margin.

SECTION CODE: B1, posterior margin en face; B2-B7, the sections from posterior to anterior; B8, anterior margin en face.

CLINICAL HISTORY:

None given.

SNOMED CODES:

T-D9100, M-88903

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration"
Entire report and diagnosis completed by:

These tests have not been

-----END OF REPORT-----

Division of Pathology and Laboratory Medicine

Source: NCI Genomic Data Commons file db694e63-fe0c-417b-a1c8-24df12280f77 (TCGA-IF-A4AK.D509BD4A-545A-41AF-B550-15E660D3CE08.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).